Somatic mutation profile of tumor specimen MMRF_2407_1_BM_CD138pos (aliquot MMRF_2407_1_BM_CD138pos_T2_KHS5U_K14045) from MMRF case MMRF_2407, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.0 years (16,789 days).
Specimen MMRF_2407_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf738c1-9ddf-4e42-a578-41dc7d49416c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2407_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2407_1_PB_Whole_C1_KHS5U_K14044; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9d05820-9fe4-464f-bf1f-d426c8c90499

The open-access MAF lists 53 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 12, Silent 8, Intron 8, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COG6 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764437648, COSV62997167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYFIP1 | c.3542A>G p.Y1181C | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs142569305; called by muse, mutect2, varscan2
- IGLV3-1 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs1299674827; called by muse, mutect2, varscan2
- LVRN | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs201368771; called by muse, mutect2, varscan2
- NOX4 | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as rs1339931205; called by muse, mutect2, varscan2
- OR9I1 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56925429; called by muse, mutect2, varscan2
- PAPPA | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs144012965; called by muse, mutect2, varscan2
- SIK2 | c.1557G>C p.M519I | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100516542; called by muse, mutect2, varscan2
- ARHGAP36 | c.1269T>A p.D423E | Missense Mutation (SNP) | VAF 88/96 reads (92%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FILIP1L | c.3204dup p.P1069Sfs*22 (on ENST00000354552 / NM_182909.3; = p.P829Sfs*22 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 83/297 reads (28%) | called by mutect2, pindel, varscan2
- LSR | c.1762G>C p.G588R (on ENST00000361790; = p.G569R on NM_015925.6) | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- PDE4A | c.1654C>T p.L552F (on ENST00000380702 / NM_001111307.2; = p.L313F on NM_006202.3) | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TENT5C | c.4del p.A2? | Frame Shift Del (DEL) | VAF 274/684 reads (40%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1251_1257del p.L418Gfs*41 | Frame Shift Del (DEL) | VAF 95/109 reads (87%) | called by mutect2, pindel, varscan2
- ZNF474 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 135/428 reads (32%) | called by muse, mutect2, varscan2
- ZNF567 | c.300C>A p.S100R (on ENST00000536254 / NM_001322913.1; = p.S69R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP13 | c.2943T>C p.S981= | Silent (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.324T>A p.S108= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- HTRA2 | c.744A>G p.S248= | Silent (SNP) | VAF 112/230 reads (49%) | catalogued as COSV99239390; called by muse, mutect2, varscan2
- KAT2B | c.630G>A p.L210= | Silent (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- MYOM3 | c.975C>T p.D325= | Silent (SNP) | VAF 84/197 reads (43%) | catalogued as COSV100293968; called by muse, mutect2, varscan2
- SLC16A6 | c.1011C>T p.A337= | Silent (SNP) | VAF 135/324 reads (42%) | called by muse, mutect2, varscan2
- VEZT | c.1977T>C p.S659= | Silent (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1581G>A p.A527= | Silent (SNP) | VAF 135/258 reads (52%) | catalogued as COSV99268282; called by muse, mutect2, varscan2
- ACIN1 | c.2298-1848_2298-1846del | Intron (DEL) | VAF 120/297 reads (40%) | catalogued as rs1383647891; called by mutect2, pindel, varscan2
- AEBP2 | c.1509-169A>G | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.*533G>A | 3'UTR (SNP) | VAF 92/137 reads (67%) | called by muse, mutect2, varscan2
- ATP5PB | c.*1449C>G | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- ATP5PB | c.*1601C>A | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- ATP5PB | c.*1750C>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- CPLX2 | c.208-24C>T | Intron (SNP) | VAF 97/348 reads (28%) | catalogued as rs371228931; called by muse, mutect2, varscan2
- DPP3 | chr11:66480110 A>T | 5'Flank (SNP) | VAF 53/198 reads (27%) | called by muse, mutect2, varscan2
- EEF2 | c.*86A>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2
- FAM167A | c.*123C>A | 3'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- FBXL8 | c.152+114C>T | Intron (SNP) | VAF 30/91 reads (33%) | catalogued as rs878998195; called by muse, mutect2, varscan2
- FKRP | c.-270C>T | 5'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- GFPT2 | c.7+731G>T | Intron (SNP) | VAF 26/83 reads (31%) | catalogued as rs1446988581; called by muse, mutect2, varscan2
- HRH3 | c.*777G>A | 3'UTR (SNP) | VAF 45/99 reads (45%) | called by muse, varscan2
- KLHL36 | c.*1483A>C | 3'UTR (SNP) | VAF 6/61 reads (10%) | catalogued as rs1378589993; called by muse, mutect2
- LRRC58 | c.*3534C>T | 3'UTR (SNP) | VAF 52/82 reads (63%) | called by muse, mutect2, varscan2
- NOP56 | c.570-39G>A | Intron (SNP) | VAF 81/144 reads (56%) | catalogued as rs200839654; called by muse, mutect2, varscan2
- NOX5 | c.*287C>T | 3'UTR (SNP) | VAF 79/202 reads (39%) | catalogued as rs1202363082; called by muse, mutect2, varscan2
- NT5DC3 | c.*3491T>A | 3'UTR (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- PHAX | c.*2230T>G | 3'UTR (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- PHC3 | c.537+1681G>C | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- RAD51AP1 | c.*332C>A | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.*2065_*2066del | 3'UTR (DEL) | VAF 4/54 reads (7%) | catalogued as rs1272222861; called by pindel, varscan2
- SCLY | c.*399G>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | catalogued as rs940876059; called by muse, mutect2, varscan2
- SIM1 | chr6:100387332 G>A | 3'Flank (SNP) | VAF 87/90 reads (97%) | catalogued as rs988308583; called by muse, mutect2, varscan2
- SLC6A5 | c.*172T>C | 3'UTR (SNP) | VAF 112/311 reads (36%) | called by muse, mutect2, varscan2
- SPRY4 | c.*3080G>A | 3'UTR (SNP) | VAF 37/114 reads (32%) | catalogued as rs554158619; called by muse, mutect2, varscan2
- SYNGR1 | c.338-117G>A | Intron (SNP) | VAF 256/540 reads (47%) | called by muse, mutect2, varscan2
- UGT2A3 | c.*416G>A | 3'UTR (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
